Surgical pathology report (de-identified scan), TCGA case TCGA-G8-6909, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Roswell Park, specimen TCGA-G8-6909-01A (Primary Tumor).

[page 1 of 4]
SPECIMENS:

- A. 4R RIGHT DISTAL PARATRACHEAL
- B. 4R RIGHT DISTAL PARATRACHEAL
- C. 4L LEFT DISTAL PARATRACHEAL
- D. 2L LEFT PROXIMAL PARATRACHEAL
- E. 4R RIGHT DISTAL PARATRACHEAL
- F. 7 SUBCARINAL
- G. 2R RIGHT PROXIMAL PARATRACHEAL
- H. ANTERIOR SEGMENT RIGHT UPPER LOBE

DIAGNOSIS:

- A. LUNG, 4R, RIGHT DISTAL PARATRACHEAL, BIOPSY:
LYMPHOHISTIOCYTIC TISSUE, NEGATIVE FOR MALIGNANCY.
- B. LUNG, 4R, RIGHT DISTAL PARATRACHEAL, BIOPSY:
LYMPHOHISTIOCYTIC TISSUE, NEGATIVE FOR MALIGNANCY.
- C. LUNG, 4L, LEFT DISTAL PARATRACHEAL, BIOPSY:
LYMPH NODE: NEGATIVE FOR MALIGNANCY.
- D. LUNG, 2L, LEFT PROXIMAL PARATRACHEAL, BIOPSY:
LYMPH NODE: NEGATIVE FOR MALIGNANCY.
- E. LUNG, 2L, LEFT PROXIMAL PARATRACHEAL, BIOPSY:
LYMPH NODE: MALIGNANT LYMPHOMA, DIFFUSE, LARGE CELL TYPE (IWF G1). SEE ALSO G FOR MARKERS.
- F. LUNG, 7, SUBCARINAL, BIOPSY:
LYMPH NODE: NEGATIVE FOR MALIGNANCY.
- G. LUNG, 2R, RIGHT PROXIMAL PARATRACHEAL, BIOPSY:
MALIGNANT LYMPHOMA, DIFFUSE LARGE CELL TYPE (IWF G1) HISTIOCYTE-RICH; DIFFUSE LARGE B CELL LYMPHOMA (WHO CLASSIFICATION). SEE NOTE.
- H. LUNG, RIGHT UPPER LOBE, ANTERIOR SEGMENT, BIOPSY:
RESPIRATORY MUCOSA WITH FOCAL SQUAMOUS METAPLASIA AND CHRONIC INFLAMMATION.

Note: The large cell lymphoma on block G is immunohistochemically positive for CD20 and CD10, and is otherwise negative for CD30, CD3, CD5, CD23, CD68, bcl-1, bcl-2, bcl-6 and D68. CD3 and CD5 highlight scattered background T-cells, whereas CD68 identifies numerous background histiocytes.

SPECIMEN(S):

- A. 4R RIGHT DISTAL PARATRACHEAL B. 4R RIGHT DISTAL PARATRACHEAL C. 4L LEFT DISTAL PARATRACHEAL D. 2L LEFT PROXIMAL PARATRACHEAL E. 4R RIGHT DISTAL PARATRACHEAL F. 7 SUBCARINAL G. 2R RIGHT PROXIMAL PARATRACHEAL H. ANTERIOR SEGMENT RIGHT UPPER LOBE

FROZEN SECTION DIAGNOSIS

FSA: Atypical lymphoid tissue. No carcinoma seen. More tissue requested. Final diagnosis deferred by

FSB: Atypical lymphoid infiltrate by Dr.

FSC and FSD: Lymphoid tissue, no tumor seen by

FSE and TPG: Atypical lymphoid infiltrate. No carcinoma seen by

CLINICAL HISTORY:

Lung mass

GROSS DESCRIPTION:

- A. 4R RIGHT DISTAL PARATRACHEAL
Received fresh for frozen section with the patient's name "4R" are multiple fragments of tan lymphoid appearing tissue measuring 0.5x0.5x0.2 cm, in aggregate. Entire specimen submitted for frozen section as FSA.
- B. 4R RIGHT DISTAL PARATRACHEAL:

[page 2 of 4]
Received fresh for frozen section with the patient's name labeled "FSB" are multiple fragments of lymphoid tissue measuring 1.0x1.0x0.3 cm. Portion is submitted for flow cytometry study, the remaining tissue is submitted for frozen as FSB.

C. 4L LEFT DISTAL PARATRACHEAL:

Received fresh for frozen section with the patient's name labeled "FSC 4L left distal paratracheal" are multiple fragments of anthracotic tissue measuring 1.5x1.0x0.5 cm. Submitted in cassette labeled FSC.

D. 2L LEFT PROXIMAL PARATRACHEAL

Received fresh for frozen section with the patient's name labeled "FSD 2L Left proximal paratracheal" are multiple fragments of anthracotic tissue measuring 5x1.0x0.5 cm. Submitted in cassette labeled FSD.

E. 4R RIGHT DISTAL PARATRACHEAL:

Received fresh for frozen section with the patient's name labeled "4R right distal paratracheal" are multiple tiny fragments of tan-grey tissue measuring 2.0x1.0x0.5 cm. Submitted into a cassette labeled E1 (FSE) and E2.

F. 7 SUBCARINAL

Received in formalin in a container with the patient's name labeled "7 subcarinal" are three red-tan fragments of soft tissue measuring 1.1 cm. in aggregate. Submitted in cassette F.

G. 2R RIGHT PROXIMAL PARATRACHEAL

Received fresh with the patient's name labeled "2R" are multiple fragments of tan-yellow fleshy tissue measuring 2.0x1.0x0.5 cm. in aggregate. Lymphoma work up was done including touch preps. The specimen is submitted in two cassettes G1 and G2.

H. ANTERIOR SEGMENT RIGHT UPPER LOBE BX

Received in formalin with the patient's name labeled "anterior segment of right upper lobe bx" are multiple red-white tiny fragments of soft tissue that measure 0.1 cm. in aggregate. Submitted in cassette H1.

[page 3 of 4]
SPECIMENS:

- A. BMBXRA
- B. Bone Marrow Aspirate

SPECIMEN(S):

- A. BMBXRA B. Bone Marrow Aspirate

CLINICAL HISTORY:

None

PRE-OPERATIVE DIAGNOSIS:

NHL

DIAGNOSIS:

BONE MARROW, RIGHT ILIAC CREST, BIOPSY, SECTIONS, IMPRINTS, SMEARS:
- TRILINEAGE HEMATOPOIESIS, **NEGATIVE FOR LYMPHOMA.**
- HISTORY OF DIFFUSE LARGE B-CELL LYMPHOMA.

TEMPLATE:

Patient Data: NO CBC

I. Aspirate - Differential (%): Yes, particle crush prep
Cells Counted 200 Cellularity estimate 1+-2+ M:E 4.1/1

Megakaryocytes: Dysplasia: Grade 0 Quantity: Decreased to normal

Myeloid cells		Monos/Lymphs		Erythroid cells/Other	
Dysplasia Grade 0				Dysplasia Grade 0	
Myeloblasts	1.5%	Monoblasts	Pronorm	1.5%	
Promyelocytes		Promonocytes		Normoblasts	16.5%
Myelocytes	16.0%	Monocytes	3.0%	Sideroblasts*	
Metamyelocytes		Lymphocytes		7.0%	Ring sideroblasts**
Bands/stabs	10.0%	Lymphoblasts		Plasma cells	1.5%
Segs	14.0%	Abnormal lymphs		Histiocytes	
Eosinophilic	8.0%	Unclass. Blasts		Other	
Basophilic		TOTAL myeloid & mono	73.5%		

*: As % of normoblasts; **: as % of all nucleated cells

Cytochemistry:

MPx	_____ %Total	_____ %Blasts	SB	_____ %Total	_____ %Blasts
CAE	_____ %Total	_____ %Blasts	ANBE	_____ %Total	_____ %Blasts
ANAE	_____ %Total	_____ %Blasts	AP	_____ %Total	_____ %Blasts
TRAP	_____ %Total	_____ %Blasts	PAS	_____ %Total	_____ %Blasts

*Abbreviations: MPx=Myeloperoxidase; SB=Sudan Black; CAE=Chloroacetate esterase; ANBE=alpha-naphthyl butyrase esterase; ANAE=alpha-naphthyl acetate esterase; AP=acid phosphatase; TRAP=tartrate resistant acid phosphatase; PAS=periodic acid Schiff.

FAB Classification:

CALGB Status:

POG Status:

Comment on Diff: History of lymphoma. Adequate hemopoiesis and slight eosinophilia seen.

II. Biopsy data: Yes

1. Cellularity: 10%-60%, average 40%
2. Myeloid/erythroid ratio: 4/1

[page 4 of 4]
- | | | | | |
|----|----------------------------|------------|---------|------------------|
| 3. | Myeloid series: | Dysplasia: | Grade 0 | Quantity: Normal |
| 4. | Erythroid series: | Dysplasia: | Grade 0 | Quantity: Normal |
| 5. | Megakaryocytes: | Dysplasia: | Grade 0 | Quantity: Normal |
| 6. | Iron stores: | Not done | | |
| 7. | Abnormal infiltrate: | None | | |
| 8. | Other: | | | |
| 9. | Comparison to Previous Bx: | NA | | |

Source: NCI Genomic Data Commons file e554ef32-056e-4c5f-8983-10b97b19680d (TCGA-G8-6909.5E9FFC0B-63AD-4720-8C82-8850F3CC57EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).